Gene-level copy-number profile of tumor specimen REBC-ADKY-TTP1-A from REBC case REBC-ADKY, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine).
Specimen REBC-ADKY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2249d4a8-5618-4b36-8220-5c111982a878.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ADKY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/4935b146-28b5-4c3a-a410-d66e9d45e2f0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 7,624; copy number 2: 51,280; copy number 3: 2.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:130,048,426–130,129,222, 5 genes (within-gene range 0–1): CYP4F27P, POTEF, AC018865.1, POTEF-AS1, RNU6-1049P.
- chr17:46,274,784–46,361,797, 3 genes: ARL17B, LRRC37A, RN7SL656P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,768. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
